Somatic mutation profile of tumor specimen 0DM8UA from CCDI case PBBZHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 16.1 years (5,871 days).
Specimen 0DM8UA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dfa0bfb-902d-4d9a-8397-83f8463ead6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fceffc6e-471b-4891-b912-92ee43927841

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA1 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 178/437 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); called by muse, varscan2
- VENTX | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 94/500 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- RNF223 | c.483C>T p.D161= | Silent (SNP) | VAF 92/208 reads (44%) | catalogued as rs893999920; called by muse, varscan2
- SBNO2 | c.3852C>A p.A1284= | Silent (SNP) | VAF 118/270 reads (44%) | called by muse, varscan2
